Somatic mutation profile of tumor specimen TCGA-G4-6299-01A (aliquot TCGA-G4-6299-01A-11D-1771-10) from TCGA case TCGA-G4-6299, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.3 years (25,318 days).
Specimen TCGA-G4-6299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13a5a5d4-2992-460d-b644-b7c798b9e1b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6299-10A (Blood Derived Normal), aliquot TCGA-G4-6299-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e2f4b9d-6bed-4067-8e54-e6b7bf0e415f

The open-access MAF lists 174 somatic variants for this specimen: 131 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 40, Nonsense Mutation 7, Frame Shift Del 6, In Frame Del 2, Frame Shift Ins 2, Splice Site 2, Splice Region 1, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 91/150 reads (61%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57923943, COSV57925041; called by muse, mutect2, varscan2
- ABCA4 | c.5326C>A p.P1776T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100933288; called by muse, mutect2, varscan2
- ABCB1 | c.3043A>T p.T1015S | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55964223; called by muse, varscan2
- ADAMTS2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as COSV51106330; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2530C>G p.Q844E | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.236); catalogued as COSV54470793; called by muse, mutect2, varscan2
- ADCK5 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs781814299, COSV58232207; called by muse, mutect2, varscan2
- ADCY5 | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 75/118 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV59204799; called by muse, mutect2, varscan2
- ADCY8 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 116/206 reads (56%) | SIFT tolerated (0.76); PolyPhen benign (0.028); catalogued as rs776939154, COSV99654585; called by muse, varscan2
- AHNAK | c.14345A>C p.K4782T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99949812; called by muse, mutect2, varscan2
- AKNAD1 | c.884A>T p.K295I | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs1007026069, COSV62203769; called by muse, mutect2, varscan2
- ALS2CL | c.539A>C p.H180P | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV59673865; called by muse, mutect2, varscan2
- AMPH | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560808720, COSV57735048; called by muse, mutect2, varscan2
- ANAPC2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.068); catalogued as COSV58809219; called by muse, varscan2
- ANKRD2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1436065232, COSV53969796; called by muse, mutect2, varscan2
- AP1G2 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58115794; called by muse, mutect2, varscan2
- AP2B1 | c.8A>C p.D3A | Missense Mutation (SNP) | VAF 91/414 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV52003669; called by muse, mutect2, varscan2
- ARID5B | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54414425, COSV54430276; called by muse, mutect2, varscan2
- ATP2B1 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99666221; called by muse, mutect2, varscan2
- BNC1 | c.2744C>G p.A915G | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as COSV61758638, COSV61759262; called by muse, mutect2, varscan2
- C1orf74 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs1169865383, COSV50561191; called by muse, mutect2, varscan2
- C5 | c.2224A>T p.I742F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV99798866; called by muse, mutect2, varscan2
- CDR2L | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61501898; called by muse, mutect2, varscan2
- CLDN8 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99729729; called by muse, mutect2, varscan2
- CMKLR1 | c.816C>A p.C272* (on ENST00000312143 / NM_001142344.2; = p.C270* on NM_004072.3) | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV56442042; called by muse, mutect2, varscan2
- CNGA4 | c.495T>A p.N165K | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV101171886; called by muse, mutect2, varscan2
- CWH43 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.536); catalogued as COSV99894219; called by muse, mutect2, varscan2
- CYLC1 | c.792G>C p.W264C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs753445496, COSV61416113; called by muse, mutect2, varscan2
- DGKI | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV99937520; called by muse, mutect2, varscan2
- DNAH11 | c.4219G>T p.D1407Y | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100181100; called by muse, mutect2, varscan2
- DYNC2H1 | c.4096A>G p.T1366A | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761604551, COSV100519880; called by muse, mutect2, varscan2
- EPB41L3 | c.305A>T p.K102M | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100550437; called by muse, mutect2, varscan2
- FAM81B | c.1025A>C p.K342T | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV51987101; called by muse, mutect2, varscan2
- FOXF1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV52288721; called by muse, mutect2, varscan2
- GLRB | c.702A>T p.K234N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV52422822; called by muse, mutect2, varscan2
- GPR61 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs746467326, COSV68178165; called by muse, mutect2, varscan2
- HEATR4 | c.842A>G p.E281G | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV100620639; called by muse, mutect2, varscan2
- HECTD1 | c.3800G>A p.R1267H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1279187861, COSV67947831; called by muse, mutect2, varscan2
- HGFAC | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs777370532, COSV58757175; called by muse, mutect2, varscan2
- HMX2 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60593050; called by muse, mutect2, varscan2
- HNRNPF | c.1096G>T p.G366W | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61562298; called by muse, mutect2, varscan2
- HOXD10 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV50891786; called by muse, mutect2, varscan2
- IFI16 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV55540417; called by muse, mutect2, varscan2
- IL12RB1 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100443224; called by muse, mutect2, varscan2
- INSM2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV99356242; called by muse, mutect2, varscan2
- KCNJ11 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs768909861, COSV60595626, COSV60595643; called by muse, mutect2, varscan2
- KLHL32 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV65115121; called by muse, mutect2, varscan2
- KMT2B | c.5590C>T p.R1864* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV55856587; called by muse, mutect2, varscan2
- LARS1 | c.3409G>A p.E1137K (on ENST00000394434 / NM_020117.11; = p.E1110K on NM_016460.3) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs201386463; ClinVar: likely benign; called by muse, mutect2, varscan2
- LHX3 | c.314G>A p.R105H (on ENST00000371748 / NM_178138.6; = p.R110H on NM_014564.5) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs917604349, COSV65581413; called by muse, varscan2
- LIG1 | c.421A>G p.S141G | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1311602068, COSV54396200; called by muse, mutect2, varscan2
- LIPE | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 43/137 reads (31%) | catalogued as COSV54925728; called by muse, mutect2, varscan2
- MBD4 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs371283287; called by muse, mutect2, varscan2
- MDN1 | c.12028A>T p.S4010C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV65530680; called by muse, mutect2, varscan2
- MERTK | c.963C>T p.V321= | Splice Region (SNP) | VAF 35/111 reads (32%) | catalogued as COSV99775389; called by muse, mutect2, varscan2
- MID2 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs372849069, COSV99465675, COSV99465712; called by muse, mutect2, varscan2
- MTA2 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1331250776, COSV53874852; called by muse, mutect2, varscan2
- MUC16 | c.1583T>G p.F528C | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV67495584; called by muse, mutect2
- MXRA8 | c.1315_1317del p.E439del | In Frame Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs764911288; called by mutect2, pindel, varscan2
- MYO15A | c.10469C>G p.T3490S | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV52766725; called by muse, mutect2, varscan2
- NRXN3 | c.1685G>A p.R562H (on ENST00000335750 / NM_001330195.2; = p.R189H on NM_004796.6) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs369032353; called by muse, mutect2, varscan2
- OBSCN | c.9602C>T p.A3201V | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.81); catalogued as COSV52818921, COSV99484778; called by muse, mutect2, varscan2
- OBSCN | c.16759G>A p.E5587K | Missense Mutation (SNP) | VAF 103/211 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99484788; called by muse, mutect2, varscan2
- OPLAH | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs781993814, COSV70679400; called by muse, varscan2
- OR4K5 | c.25G>C p.V9L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV60005334; called by muse, mutect2, varscan2
- OR51E1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.54); catalogued as rs575981363, COSV67809895; called by muse, mutect2, varscan2
- OR52L1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs763535932, COSV59989257; called by muse, mutect2, varscan2
- OR5D18 | c.110A>C p.N37T | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100450617, COSV61738710; called by muse, mutect2, varscan2
- OR5T3 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs201185677, COSV57379933; called by muse, mutect2, varscan2
- OR7G1 | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs546098161, COSV99528824; called by muse, mutect2, varscan2
- OTUD7B | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); catalogued as rs1258596043, COSV64916524; called by muse, mutect2, varscan2
- PARP14 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771490414, COSV71735627; called by muse, mutect2, varscan2
- PCDHB8 | c.1085C>A p.P362H | Missense Mutation (SNP) | VAF 113/644 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV50818914; called by muse, mutect2, varscan2
- PDE7A | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs1176481998, COSV67524809; called by muse, mutect2, varscan2
- PLA2G4F | c.2074G>C p.A692P | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV51826739, COSV51829627; called by muse, mutect2, varscan2
- PPRC1 | c.4765C>T p.R1589C | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53388737; called by muse, mutect2, varscan2
- PRR23B | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.584); catalogued as COSV61494951; called by muse, mutect2, varscan2
- PRSS1 | c.41-1G>T p.X14_splice | Splice Site (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100298517; called by muse, mutect2, varscan2
- PTK2 | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61793070; called by muse, mutect2, varscan2
- RDH16 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs200529763, COSV62458825; called by muse, mutect2, varscan2
- RDH5 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57676110, COSV57677474; called by muse, mutect2, varscan2
- RYR1 | c.14716G>A p.A4906T | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1467742744, COSV100617115; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- RYR3 | c.10422G>T p.W3474C (on ENST00000389232; = p.W3475C on NM_001036.6) | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66811077; called by muse, mutect2, varscan2
- SENP7 | c.2081A>G p.E694G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100053952; called by muse, mutect2, varscan2
- SIGLEC8 | c.449T>C p.V150A | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100367400, COSV100367412; called by muse, mutect2, varscan2
- SLC26A7 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748779061, COSV52588193, COSV99404483; called by muse, mutect2, varscan2
- SLC4A8 | c.1994C>A p.A665D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60658442; called by muse, mutect2, varscan2
- SPART | c.1964del p.T655Rfs*4 | Frame Shift Del (DEL) | VAF 131/259 reads (51%) | catalogued as COSV62088702, COSV62089415; called by mutect2, pindel, varscan2
- SPSB4 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs151301252; called by muse, mutect2, varscan2
- SPTA1 | c.6448G>T p.A2150S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV63756731, COSV63759956; called by muse, mutect2, varscan2
- SYNGAP1 | c.3246G>C p.Q1082H | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV53386882; called by muse, mutect2, varscan2
- TBC1D10C | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56704388; called by muse, mutect2, varscan2
- TBXT | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs771064715, COSV51620224; called by muse, mutect2, varscan2
- TEX43 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 29/52 reads (56%) | catalogued as COSV64036384; called by muse, mutect2, varscan2
- TFAP2D | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs780379700, COSV50410964; called by muse, mutect2, varscan2
- TM7SF3 | c.1404C>A p.N468K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as COSV58004181; called by muse, mutect2, varscan2
- TMC6 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59811803; called by muse, mutect2, varscan2
- TNR | c.3715G>A p.A1239T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755878985, COSV54901983; called by mutect2, varscan2
- TNS4 | c.1912G>T p.V638L | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV99564181; called by muse, mutect2, varscan2
- TRHDE | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs925737451, COSV53868213, COSV99668968; called by muse, mutect2, varscan2
- TRIO | c.3082del p.E1028Rfs*29 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as COSV60096576; called by mutect2, varscan2
- TRPM2 | c.3147C>G p.N1049K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100309380; called by muse, mutect2, varscan2
- TSPAN31 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 103/350 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57277209; called by muse, mutect2, varscan2
- TTC39A | c.1645C>G p.L549V (on ENST00000447632 / NM_001297665.1; = p.L514V on NM_001080494.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99396795, COSV99397149; called by muse, mutect2, varscan2
- TTLL2 | c.1738_1740del p.I580del | In Frame Del (DEL) | VAF 18/45 reads (40%) | catalogued as COSV53446025; called by mutect2, pindel, varscan2
- VCAN | c.2867G>C p.S956T | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV54117330; called by muse, mutect2, varscan2
- WNT3A | c.619G>A p.G207R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52730161, COSV52734262; called by muse, mutect2, varscan2
- ZBTB40 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1195233708; called by muse, mutect2
- ZNF107 | c.1459A>G p.K487E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV100788543; called by muse, mutect2, varscan2
- ZNF185 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100248684; called by muse, mutect2, varscan2
- ZNF254 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV100298314; called by muse, mutect2, varscan2
- ZNF280B | c.496A>C p.N166H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100840460; called by muse, mutect2, varscan2
- ZNF527 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs755325433, COSV62235775; called by mutect2, varscan2
- ZNF578 | c.778A>C p.K260Q | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV69737674; called by muse, mutect2, varscan2
- ZNF660 | c.298C>A p.H100N | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59550010; called by muse, mutect2, varscan2
- ZNF682 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV62068605; called by muse, mutect2, varscan2
- ZNF689 | c.1408T>A p.W470R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV54910158; called by muse, mutect2, varscan2
- ZNF763 | c.226G>T p.E76* (on ENST00000358987 / NM_001367172.2; = p.E79* on NM_001012753.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as COSV59688968; called by muse, mutect2, varscan2
- ZNF783 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs775146967, COSV65185305; called by muse, mutect2, varscan2
- ZNF98 | c.349C>G p.R117G | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100757648, COSV63340057; called by muse, mutect2, varscan2
- A2M | c.2997_2998del p.E999Dfs*23 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- FANCD2 | c.3745dup p.I1249Nfs*2 | Frame Shift Ins (INS) | VAF 26/60 reads (43%) | called by mutect2, varscan2
- FBXO28 | c.625_637del p.E209Kfs*7 | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | called by mutect2, pindel
- MARK1 | c.539dup p.H180Qfs*3 | Frame Shift Ins (INS) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- PPFIA4 | c.3005T>C p.I1002T (on ENST00000447715; = p.I1003T on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRDM2 | c.4169_4170del p.G1390Efs*14 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- RNF43 | c.883del p.H295Ifs*124 | Frame Shift Del (DEL) | VAF 40/75 reads (53%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.1117T>C p.Y373H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, varscan2
- ZMYM3 | c.3279_3280+12del p.X1093_splice | Splice Site (DEL) | VAF 22/41 reads (54%) | called by mutect2, pindel, varscan2
- ANO1 | c.1071C>T p.C357= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs570844488, COSV60283010; called by muse, mutect2, varscan2
- ASPDH | c.564G>A p.P188= (on ENST00000389208 / NM_001114598.2; = p.P83= on NM_001024656.3) | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs370240584; called by muse, mutect2, varscan2
- CARMIL3 | c.2367C>T p.A789= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs79873279; called by muse, mutect2, varscan2
- CDC42BPA | c.858G>A p.S286= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs1267392725, COSV62011385; called by muse, mutect2, varscan2
- CDH23 | c.8604G>C p.V2868= | Silent (SNP) | VAF 46/151 reads (30%) | catalogued as COSV56491354; called by muse, mutect2, varscan2
- CDK2AP2 | c.216C>T p.S72= | Silent (SNP) | VAF 76/179 reads (42%) | catalogued as rs777806095, COSV56874604; called by muse, mutect2, varscan2
- CHAF1A | c.1572C>T p.H524= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1432455117, COSV56676578; called by muse, mutect2, varscan2
- CPN1 | c.933C>T p.C311= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs977753977, COSV64942852; called by muse, mutect2, varscan2
- CREBBP | c.399G>C p.L133= | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs1490433676, COSV99272321; called by muse, mutect2, varscan2
- CYP17A1 | c.384G>A p.A128= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV64004702; called by muse, mutect2, varscan2
- DCST2 | c.402C>T p.T134= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as rs753554045, COSV55054824; called by muse, mutect2, varscan2
- DLX2 | c.978G>A p.T326= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as COSV52232978; called by muse, mutect2, varscan2
- DRGX | c.543T>C p.S181= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV65137648; called by muse, mutect2, varscan2
- EPYC | c.420G>A p.P140= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1565871112, COSV99664928; called by muse, mutect2, varscan2
- FIGNL2 | c.978C>T p.G326= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1281193133; called by muse, mutect2, varscan2
- GABRA5 | c.564T>G p.P188= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- GRM5 | c.1125C>T p.S375= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100554725; called by muse, mutect2, varscan2
- HLF | c.45C>A p.I15= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV56832028; called by muse, mutect2, varscan2
- HYDIN | c.15315G>T p.G5105= | Silent (SNP) | VAF 44/68 reads (65%) | catalogued as COSV66642520; called by muse, mutect2, varscan2
- KCNA2 | c.744C>T p.A248= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs770861576, COSV60368821; called by muse, mutect2, varscan2
- LORICRIN | c.930G>A p.P310= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as COSV64201794; called by muse, mutect2, varscan2
- MFAP3L | c.153C>T p.A51= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV64373142; called by muse, mutect2, varscan2
- NEB | c.9814C>A p.R3272= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV51461660; called by muse, mutect2, varscan2
- NEXMIF | c.2616G>A p.Q872= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1449765497; called by muse, mutect2
- NUP210 | c.3612C>T p.A1204= | Silent (SNP) | VAF 46/71 reads (65%) | catalogued as rs1022896649, COSV54414456; called by muse, mutect2, varscan2
- OPLAH | c.828C>T p.P276= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV101470965; called by muse, varscan2
- OR2S2 | c.669C>T p.I223= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs769590754, COSV59531367; called by muse, mutect2, varscan2
- OR4D6 | c.723G>A p.T241= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as rs758572267, COSV100271754, COSV55660072; called by muse, mutect2, varscan2
- OR51G2 | c.510A>G p.R170= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100432247; called by muse, mutect2, varscan2
- PHRF1 | c.2226G>C p.G742= (on ENST00000264555 / NM_001286581.2; = p.G741= on NM_020901.4) | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV52763082; called by mutect2, varscan2
- PSD4 | c.384C>T p.N128= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV55530451; called by muse, mutect2, varscan2
- RHAG | c.84G>A p.T28= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as rs370019012; called by muse, varscan2
- RNF19B | c.2115G>A p.P705= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs138818373, COSV99331798; called by muse, mutect2, varscan2
- SLC47A1 | c.909C>A p.I303= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV54504303; called by muse, mutect2, varscan2
- SZT2 | c.9930A>T p.A3310= (on ENST00000634258 / NM_001365999.1; = p.A3253= on NM_015284.4) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV65095483; called by muse, mutect2, varscan2
- THOP1 | c.1377G>A p.A459= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs577622918, COSV57021247; called by muse, mutect2, varscan2
- TOX | c.930T>C p.Y310= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs370108565; called by muse, mutect2, varscan2
- TRAPPC10 | c.132A>G p.E44= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as COSV52381733; called by muse, mutect2, varscan2
- TVP23A | c.390C>T p.I130= | Silent (SNP) | VAF 22/33 reads (67%) | catalogued as COSV51595806; called by muse, mutect2, varscan2
- ZNF676 | c.1650G>A p.S550= (on ENST00000650058; = p.S518= on NM_001001411.3) | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs776190887, COSV68092278; called by muse, mutect2, varscan2
- AGAP7P | n.799G>C | RNA (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- FYB1 | c.1907+1622C>T | Intron (SNP) | VAF 23/41 reads (56%) | catalogued as COSV60947086; called by muse, mutect2, varscan2
- SAYSD1 | c.*1G>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100010266; called by muse, mutect2, varscan2
